Somatic mutation profile of tumor specimen HCM-CSHL-0853-C56-06A (aliquot HCM-CSHL-0853-C56-06A-11D-A881-36) from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5aa3a310-a5b1-45e7-b1dc-80cff6bccfda.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0853-C56-10A (Blood Derived Normal), aliquot HCM-CSHL-0853-C56-10A-01D-A881-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4074f4f7-30ac-49da-baa5-13d67518d740

The open-access MAF lists 28 somatic variants for this specimen: 18 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 134/291 reads (46%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- C2CD2L | c.2038G>A p.A680T | Missense Mutation (SNP) | VAF 234/979 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.187); catalogued as rs940210543; called by muse, mutect2, varscan2
- CFAP47 | c.1720C>T p.R574C | Missense Mutation (SNP) | VAF 146/402 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.013); catalogued as rs760933446, COSV52884417; called by muse, mutect2, varscan2
- CNOT1 | c.4196G>A p.R1399Q | Missense Mutation (SNP) | VAF 137/338 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV55320287; called by muse, mutect2, varscan2
- CTNNA2 | c.1897C>T p.P633S | Missense Mutation (SNP) | VAF 62/247 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.982); catalogued as COSV58173470; called by muse, mutect2, varscan2
- DOCK8 | c.6136C>A p.L2046I | Missense Mutation (SNP) | VAF 144/336 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs747086561; called by muse, mutect2, varscan2
- FAM160A2 | c.692G>A p.R231H | Missense Mutation (SNP) | VAF 136/568 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768160220; called by muse, mutect2, varscan2
- FLT3 | c.2440G>A p.A814T | Missense Mutation (SNP) | VAF 112/387 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201208287, COSV54046882, COSV54065904; called by muse, mutect2, varscan2
- PHKA2 | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs1202167585, COSV66052129; called by muse, mutect2
- PPFIA4 | c.2323G>C p.D775H (on ENST00000447715; = p.D776H on NM_001304331.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 150/538 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.572); catalogued as rs774650502; called by muse, mutect2, varscan2
- SART1 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 58/358 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV56711524; called by muse, mutect2, varscan2
- FRRS1 | c.191T>G p.I64S | Missense Mutation (SNP) | VAF 92/314 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, varscan2
- GRSF1 | c.352A>G p.S118G | Missense Mutation (SNP) | VAF 66/212 reads (31%) | SIFT tolerated (0.32); PolyPhen benign (0.025); called by mutect2, varscan2
- ITIH4 | c.1168G>C p.V390L | Missense Mutation (SNP) | VAF 107/219 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- PLEKHM1 | c.2455C>G p.P819A | Missense Mutation (SNP) | VAF 22/655 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.493); called by muse, mutect2
- PRSS36 | c.2477G>A p.S826N | Missense Mutation (SNP) | VAF 191/495 reads (39%) | SIFT tolerated (0.09); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- RCN3 | c.953G>C p.G318A | Missense Mutation (SNP) | VAF 153/359 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SPATA18 | c.772C>T p.R258W | Missense Mutation (SNP) | VAF 127/435 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- AP3B1 | c.1932C>T p.P644= | Silent (SNP) | VAF 83/188 reads (44%) | catalogued as rs368771979; called by muse, mutect2, varscan2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 90/326 reads (28%) | called by muse, mutect2, varscan2
- COL7A1 | c.6897A>G p.G2299= | Silent (SNP) | VAF 113/300 reads (38%) | catalogued as rs749586805; called by muse, mutect2, varscan2
- KIAA1522 | c.777C>A p.T259= (on ENST00000373480 / NM_001198972.2; = p.T318= on NM_020888.3) | Silent (SNP) | VAF 194/696 reads (28%) | called by muse, mutect2, varscan2
- MAPK8IP3 | c.867C>T p.N289= | Silent (SNP) | VAF 218/486 reads (45%) | catalogued as rs374654639; called by muse, mutect2, varscan2
- NCAPH | c.687C>T p.N229= | Silent (SNP) | VAF 118/426 reads (28%) | catalogued as rs760742546; called by muse, mutect2, varscan2
- NR0B2 | c.138C>T p.P46= | Silent (SNP) | VAF 170/384 reads (44%) | catalogued as rs370821222; called by muse, mutect2, varscan2
- SHOC1 | c.2052G>A p.L684= | Silent (SNP) | VAF 85/298 reads (29%) | called by muse, varscan2
- TNC | c.5031A>C p.I1677= | Silent (SNP) | VAF 83/721 reads (12%) | called by muse, mutect2, varscan2
- HSPB7 | chr1:16019339 del CTGT | 5'Flank (DEL) | VAF 182/777 reads (23%) | called by mutect2, pindel, varscan2
